Somatic mutation profile of tumor specimen TCGA-CQ-A4CA-01A (aliquot TCGA-CQ-A4CA-01A-11D-A25D-08) from TCGA case TCGA-CQ-A4CA, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Ventral surface of tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2.
Specimen TCGA-CQ-A4CA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82310484-9bdf-47c0-9875-52dfacd274c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-A4CA-10A (Blood Derived Normal), aliquot TCGA-CQ-A4CA-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42a1368a-2e87-40c6-889a-7b4783e5aa7d

The open-access MAF lists 76 somatic variants for this specimen: 52 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 23, Nonsense Mutation 7, Splice Region 3, Frame Shift Del 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP11B | c.3232C>G p.L1078V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs940518786; called by muse, mutect2, varscan2
- CUL9 | c.4555C>T p.R1519W | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139277408; called by muse, mutect2, varscan2
- CXCL10 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1176324107; called by muse, mutect2, varscan2
- DNAH5 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99452005; called by muse, mutect2
- DPP8 | c.2360A>G p.Y787C (on ENST00000341861 / NM_001320875.2; = p.Y671C on NM_017743.6) | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55677611; called by muse, mutect2, varscan2
- FUS | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99568928; called by muse, mutect2
- GPBP1L1 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1435847227; called by muse, mutect2
- IMPG1 | c.2212G>C p.E738Q | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV63113184; called by muse, mutect2, varscan2
- KRT85 | c.1513C>A p.R505S | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.204); catalogued as COSV99225686; called by muse, mutect2
- MYEF2 | c.717T>C p.N239= | Splice Region (SNP) | VAF 8/74 reads (11%) | catalogued as rs778559951; called by muse, mutect2, varscan2
- RALYL | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs766785304, COSV72819337; called by muse, mutect2, varscan2
- RBM39 | c.452A>T p.D151V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53614590, COSV53614751; called by muse, mutect2, varscan2
- RGS7BP | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.806); catalogued as rs151111266; called by muse, mutect2, varscan2
- SLC25A30 | c.709G>C p.G237R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs1354960717; called by muse, mutect2, varscan2
- TMIE | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs397517866; called by muse, mutect2, varscan2
- USP28 | c.1813A>T p.I605F | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99135254; called by muse, mutect2
- ZNF496 | c.57G>C p.R19S | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.746); catalogued as COSV54179655, COSV99665648; called by muse, mutect2, varscan2
- ARHGAP20 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.056); called by muse, mutect2
- CCDC47 | c.1274G>C p.R425T | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CCDC86 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by mutect2, varscan2
- CDKL2 | c.657T>A p.G219= | Splice Region (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- CEP112 | c.2475G>C p.Q825H (on ENST00000392769 / NM_001353127.1; = p.Q81H on NM_001037325.3) | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- CEP192 | c.3582T>G p.D1194E | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- CLIC4 | c.497A>G p.N166S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FAT4 | c.10181A>T p.N3394I | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.999); called by muse, mutect2
- GGCX | c.1880del p.N627Mfs*20 | Frame Shift Del (DEL) | VAF 12/123 reads (10%) | called by mutect2, pindel, varscan2
- GRIP1 | c.2116G>C p.G706R (on ENST00000359742 / NM_001379345.1; = p.G654R on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- GRM7 | c.929G>C p.W310S | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- INTS8 | c.1364A>G p.Y455C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- MAGEF1 | c.119A>G p.E40G | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- MRPL37 | c.831A>G p.T277= | Splice Region (SNP) | VAF 41/101 reads (41%) | called by muse, mutect2, varscan2
- MSH2 | c.2233A>G p.I745V | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.098); called by muse, mutect2
- MYCBP2 | c.5390A>T p.N1797I (on ENST00000357337; = p.N1835I on NM_015057.5) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDUFA5 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2
- NMUR1 | c.1069A>T p.S357C | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- NOTCH1 | c.2861G>A p.C954Y | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHF11 | c.334T>C p.F112L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PIWIL2 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- PPARD | c.703C>A p.L235M | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- PPFIA2 | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- PRAMEF15 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 59/302 reads (20%) | called by muse, mutect2, varscan2
- RALGAPB | c.4079C>G p.S1360* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- SHCBP1L | c.1426C>T p.H476Y | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- SPRY2 | c.165_166insTC p.T56Sfs*57 | Frame Shift Ins (INS) | VAF 18/103 reads (17%) | called by pindel, varscan2
- SYNM | c.4691G>A p.W1564* (on ENST00000336292 / NM_145728.3; = p.W1252* on NM_015286.6) | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- SYTL4 | c.1580A>G p.E527G | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- TENM2 | c.6267T>A p.F2089L (on ENST00000518659 / NM_001122679.2; = p.F1850L on NM_001080428.3) | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TNS1 | c.3871G>A p.A1291T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBGCP5 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- USP28 | c.1812T>A p.Y604* | Nonsense Mutation (SNP) | VAF 5/102 reads (5%) | called by muse, mutect2
- ZNF106 | c.2330C>T p.T777I | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF608 | c.3150G>T p.K1050N | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- AMIGO3 | c.1365C>T p.V455= | Silent (SNP) | VAF 21/132 reads (16%) | catalogued as rs758864363, COSV57537775; called by muse, mutect2, varscan2
- CCDC141 | c.4146T>C p.Y1382= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- CD70 | c.411C>T p.S137= | Silent (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- DHDDS | c.613C>A p.R205= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV52576968; called by muse, mutect2, varscan2
- EFTUD2 | c.2424C>T p.I808= | Silent (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- FNDC1 | c.1845G>A p.S615= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs1217396894, COSV51941689; called by muse, mutect2
- FNDC1 | c.3804C>T p.T1268= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1036829724; called by muse, mutect2
- GPR162 | c.1278A>T p.P426= (on ENST00000311268 / NM_019858.2; = p.P142= on NM_014449.2) | Silent (SNP) | VAF 19/157 reads (12%) | called by muse, mutect2, varscan2
- GRIA1 | c.333G>A p.P111= | Silent (SNP) | VAF 31/131 reads (24%) | catalogued as rs750448884, COSV53597890, COSV99603170; called by muse, mutect2, varscan2
- GSTM3 | c.393C>T p.Y131= | Silent (SNP) | VAF 8/115 reads (7%) | catalogued as rs1405300129; called by muse, mutect2
- HOXC9 | c.219G>A p.S73= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV57716666; called by muse, mutect2, varscan2
- KNOP1 | c.84A>G p.R28= | Silent (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- PALM2AKAP2 | c.1440G>C p.V480= (on ENST00000259318 / NM_001136562.3; = p.V711= on NM_007203.5) | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as rs906587146; called by muse, mutect2
- PJVK | c.1032T>C p.F344= | Silent (SNP) | VAF 24/142 reads (17%) | called by muse, mutect2, varscan2
- PPAT | c.1125A>G p.V375= | Silent (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- RXFP3 | c.180G>A p.A60= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as rs747578372; called by muse, mutect2, varscan2
- SLC7A14 | c.810C>A p.I270= | Silent (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- ST18 | c.1170G>A p.S390= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as rs375570357, COSV52486527; called by muse, mutect2, varscan2
- THUMPD3 | c.1299C>T p.V433= | Silent (SNP) | VAF 47/224 reads (21%) | called by muse, mutect2, varscan2
- TMC3 | c.285C>G p.T95= | Silent (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2, varscan2
- TTN | c.26625A>G p.K8875= (on ENST00000591111; = p.K7948= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/216 reads (7%) | called by muse, mutect2
- UROC1 | c.1689C>T p.D563= | Silent (SNP) | VAF 21/161 reads (13%) | catalogued as rs576867756, COSV52029999; called by muse, mutect2, varscan2
- ZNF345 | c.1050C>G p.T350= | Silent (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- TMC5 | c.1049-3327C>T | Intron (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
